Somatic mutation profile of tumor specimen TCGA-UZ-A9PK-01A (aliquot TCGA-UZ-A9PK-01A-11D-A382-10) from TCGA case TCGA-UZ-A9PK, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9PK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54c78329-de01-4f88-b646-5c69b65138c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PK-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PK-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74efc50b-60fb-4f39-870b-bd8b77660152

The open-access MAF lists 81 somatic variants for this specimen: 61 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Frame Shift Del 8, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 2, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.4109T>C p.L1370P | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100966748; called by muse, mutect2, varscan2
- ALPK2 | c.1555A>G p.R519G | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100864863; called by muse, mutect2, varscan2
- BAP1 | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99964553; called by muse, mutect2, varscan2
- BMP2K | c.2174A>G p.K725R | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV99785476; called by muse, mutect2
- C16orf86 | c.932_933insT p.L312Afs*21 | Frame Shift Ins (INS) | VAF 47/116 reads (41%) | catalogued as COSV54754229, COSV99708353; called by mutect2, pindel, varscan2
- CC2D1B | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99430342; called by muse, mutect2, varscan2
- CNKSR3 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV101401422; called by muse, varscan2
- CUBN | c.3137C>G p.T1046R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV100913642; called by muse, mutect2, varscan2
- CYFIP2 | c.996G>T p.W332C | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100557857; called by muse, mutect2, varscan2
- DEGS1 | c.431T>G p.I144S | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100083479; called by muse, mutect2, varscan2
- DMRT3 | c.1337C>G p.S446* | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as COSV99506053, COSV99506100; called by muse, mutect2, varscan2
- DNAAF1 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100533841; called by muse, mutect2, varscan2
- DNAH9 | c.12832C>T p.L4278F | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754381795, COSV99307380; called by muse, mutect2, varscan2
- EFNA1 | c.331T>C p.F111L | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310508; called by muse, mutect2, varscan2
- ELAVL3 | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100820880; called by muse, mutect2, varscan2
- FAM71B | c.542G>C p.S181T | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100262333; called by muse, mutect2, varscan2
- FNDC1 | c.1781G>A p.R594K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51931708; called by muse, mutect2, varscan2
- GMCL1 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99247951; called by muse, mutect2, varscan2
- H2BC21 | c.19T>A p.S7T | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100480205; called by muse, mutect2, varscan2
- HSD17B11 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV64155373; called by muse, mutect2, varscan2
- IFNK | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV99219028; called by muse, mutect2, varscan2
- KCNV2 | c.1121A>G p.Q374R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.795); catalogued as COSV101172648; called by muse, mutect2, varscan2
- LCA5 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs771098708, COSV63970958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIPE | c.2783T>C p.L928P | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); catalogued as COSV99734437; called by muse, mutect2, varscan2
- LMO7 | c.4735C>T p.P1579S (on ENST00000357063; = p.P1260S on NM_005358.5) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs1189999707, COSV100413901; called by muse, mutect2, varscan2
- LRRFIP2 | c.1656G>T p.Q552H | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100368729; called by muse, mutect2, varscan2
- LRRIQ4 | c.7A>T p.K3* | Nonsense Mutation (SNP) | VAF 225/412 reads (55%) | catalogued as COSV100540407; called by muse, mutect2, varscan2
- MARF1 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); catalogued as COSV100706413; called by muse, mutect2, varscan2
- MYH13 | c.3508A>G p.K1170E | Missense Mutation (SNP) | VAF 109/198 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV99355641; called by muse, mutect2, varscan2
- MYORG | c.1573T>G p.W525G | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99898862; called by muse, mutect2, varscan2
- NBN | c.1845+1G>A p.X615_splice | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99620188; called by muse, mutect2, varscan2
- NDST4 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99998042; called by muse, mutect2, varscan2
- NUDT2 | c.392T>C p.M131T | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs368502630; called by muse, mutect2, varscan2
- POFUT1 | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100998410; called by muse, mutect2, varscan2
- PTCD3 | c.785T>C p.M262T | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV99606690; called by muse, mutect2, varscan2
- RNF17 | c.2077T>A p.F693I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55035592, COSV99694518; called by muse, mutect2, varscan2
- SFMBT2 | c.1061T>C p.L354S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.992); catalogued as COSV100739713; called by muse, mutect2, varscan2
- SIPA1L1 | c.4834G>T p.D1612Y | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100666124, COSV62168401; called by muse, mutect2, varscan2
- SLC16A13 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100338768; called by muse, mutect2, varscan2
- SMARCA4 | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV60794995, COSV60797565; called by muse, mutect2, varscan2
- THNSL2 | c.733T>A p.S245T | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV100147709; called by muse, mutect2, varscan2
- TNC | c.5360A>G p.E1787G | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759543276, COSV100406354; called by muse, varscan2
- TNNI3K | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58553505; called by muse, mutect2, varscan2
- UBXN6 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs563472721, COSV56673428; called by muse, mutect2, varscan2
- USP11 | c.1957G>A p.D653N (on ENST00000218348; = p.D610N on NM_001371072.1) | Missense Mutation (SNP) | VAF 68/99 reads (69%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.508); catalogued as COSV99511213; called by muse, mutect2, varscan2
- VPS13B | c.10337A>G p.E3446G | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV100663827; called by muse, mutect2, varscan2
- WDR89 | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1337954010, COSV99962597; called by muse, mutect2, varscan2
- WNK1 | c.1620G>T p.M540I | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100268799; called by muse, mutect2, varscan2
- XIRP1 | c.1539G>T p.R513S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100454011; called by muse, mutect2, varscan2
- ZBTB32 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs866223247, COSV99386294; called by muse, mutect2, varscan2
- ANK1 | c.3510_3513del p.R1171Cfs*17 | Frame Shift Del (DEL) | VAF 69/225 reads (31%) | called by mutect2, pindel, varscan2
- ANPEP | c.280_295del p.T94Afs*73 | Frame Shift Del (DEL) | VAF 10/101 reads (10%) | called by mutect2, pindel, varscan2
- DGKQ | c.1579+1dup p.X527_splice | Splice Site (INS) | VAF 39/127 reads (31%) | called by mutect2, pindel, varscan2
- DPCD | c.166dup p.S56Kfs*12 | Frame Shift Ins (INS) | VAF 27/100 reads (27%) | called by mutect2, pindel, varscan2
- DR1 | c.42del p.R15Efs*7 | Frame Shift Del (DEL) | VAF 34/98 reads (35%) | called by mutect2, varscan2
- ENTPD4 | c.148del p.S50Lfs*4 | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | called by mutect2, pindel, varscan2
- LDLR | c.816_817del p.V273Dfs*27 | Frame Shift Del (DEL) | VAF 41/122 reads (34%) | called by mutect2, pindel, varscan2
- NAALADL2 | c.1503del p.F501Lfs*31 | Frame Shift Del (DEL) | VAF 90/172 reads (52%) | called by mutect2, varscan2
- NHLRC2 | c.746del p.L249Wfs*36 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- NRDE2 | c.1309del p.I437Ffs*9 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
- TIGD6 | c.785dup p.N262Kfs*2 | Frame Shift Ins (INS) | VAF 50/171 reads (29%) | called by mutect2, pindel, varscan2
- ABCC1 | c.3468C>T p.N1156= | Silent (SNP) | VAF 98/178 reads (55%) | catalogued as rs766636573, COSV100580416; called by muse, mutect2, varscan2
- ALPK2 | c.1749T>C p.T583= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV100864859; called by muse, mutect2, varscan2
- CCDC158 | c.1260A>G p.E420= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV101187396; called by muse, mutect2, varscan2
- CPXM2 | c.1692C>T p.D564= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs547897756, COSV53861729; called by muse, mutect2, varscan2
- DLEC1 | c.5226A>G p.Q1742= | Silent (SNP) | VAF 81/164 reads (49%) | catalogued as COSV100086511; called by muse, mutect2, varscan2
- ECM1 | c.78G>T p.T26= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs200429908, COSV100682335; called by muse, mutect2, varscan2
- EP300 | c.2067T>C p.P689= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV99609975; called by muse, mutect2, varscan2
- FAM241A | c.138G>C p.P46= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100551320; called by muse, mutect2, varscan2
- FOXO3 | c.1890T>C p.S630= | Silent (SNP) | VAF 86/457 reads (19%) | catalogued as COSV100670241; called by muse, varscan2
- HABP4 | c.912A>G p.R304= | Silent (SNP) | VAF 101/310 reads (33%) | catalogued as COSV100928278; called by muse, mutect2, varscan2
- HERC4 | c.222A>G p.K74= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as COSV101034982; called by muse, mutect2, varscan2
- LRFN2 | c.1107G>A p.T369= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs768787058, COSV100599991; called by muse, mutect2, varscan2
- ODF3L2 | c.483T>C p.P161= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV99199233; called by muse, mutect2, varscan2
- PPP1R15A | c.444A>T p.I148= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV99566286; called by muse, mutect2, varscan2
- SIAH1 | c.381C>T p.S127= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV99589561; called by muse, mutect2, varscan2
- SMG8 | c.1602G>A p.V534= | Silent (SNP) | VAF 107/214 reads (50%) | catalogued as COSV99959094; called by muse, mutect2, varscan2
- SSBP2 | c.810T>C p.T270= | Silent (SNP) | VAF 152/401 reads (38%) | catalogued as COSV100284279, COSV57798381; called by muse, mutect2, varscan2
- DOCK8 | chr9:214701 G>T | 5'Flank (SNP) | VAF 39/97 reads (40%) | catalogued as COSV101213726; called by muse, mutect2, varscan2
- HERC2P3 | n.1337C>G | RNA (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.813G>T | RNA (SNP) | VAF 55/149 reads (37%) | catalogued as COSV99683710; called by muse, mutect2, varscan2
